Gene-level copy-number profile of tumor specimen HCM-BROD-0417-C71-01A from HCMI case HCM-BROD-0417-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.0 years (18,275 days).
Specimen HCM-BROD-0417-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 70d685da-0637-4d4a-89e6-c490e928abd6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0417-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/d1b5cbf6-d94b-4718-a121-19ac1d3442b8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 11,246; copy number 2: 43,026; copy number 3: 3,427; copy number 4: 412; copy number 5: 87; copy number 15: 71; copy number 16: 34; copy number 17: 38; copy number 18: 8.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:629,062–634,922, 8 genes (within-gene range 0–2): MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12.
- chr5:165,349,030–166,155,439, 6 genes: AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1.
- chr9:21,966,929–23,438,700, 14 genes (within-gene range 0–1): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr10:46,337,224–46,832,476, 22 genes: AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R, GPRIN2, SYT15, AL356056.2, AL356056.1, SHLD2P1, LINC02637, RHEBP1, RN7SL248P, CTSLP3, GLUD1P2, AL731733.1, BMS1P1, RNA5SP311, AGAP13P.
- chr22:18,623,339–18,719,341, 4 genes: SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 238 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:53,377,641–57,724,655, 95 genes, copy number 15–18 (broad region; genes not listed).
- chr9:31,165,618–32,334,354, 8 genes, copy number 5: AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23, RNA5SP281, SLC25A5P8.
- chr12:108,288,044–109,268,226, 29 genes, copy number 5: CMKLR1, LINC01498, FICD, SART3, AC008119.1, ISCU, TMEM119, SELPLG, AC007569.1, MIR4496, CORO1C, RNU7-169P, Y_RNA, AC087893.1, SSH1, AC087893.3, AC087893.2, MIR619, DAO, SVOP, RNU6-361P, AC190387.1, USP30, USP30-AS1, RNA5SP372, ALKBH2, UNG, AC007637.1, ACACB.
- chr12:113,583,886–114,113,489, 9 genes, copy number 5: LINC01234, DYNLL1P4, RBM19, AC009731.1, AC073863.1, AC010183.1, AC010183.2, HAUS8P1, GLULP5.
- chr12:114,929,757–115,364,745, 7 genes, copy number 5: AC009804.1, AC008125.1, AC078880.1, AC078880.3, AC078880.4, AC078880.5, AC078880.2.
- chr12:115,717,725–115,886,137, 5 genes, copy number 5: RN7SL865P, AC009387.1, LINC02463, AC012157.1, AC012157.3.
- chr12:117,099,481–118,136,026, 13 genes, copy number 5 (within-gene range 4–5): TESC-AS1, FBXO21, NOS1, ELOCP32, AC073864.1, KSR2, AC084291.1, RFC5, AC131159.2, WSB2, AC131159.1, VSIG10, AC131238.1.
- chr12:119,334,712–119,877,320, 8 genes, copy number 5: CCDC60, AC002070.1, TMEM233, RN7SKP197, PRKAB1, CIT, AC002563.1, MIR1178.
- chr12:124,946,825–125,164,918, 8 genes, copy number 5: DHX37, BRI3BP, THRIL, AC122688.1, AACS, AC122688.3, AC122688.2, AC122688.4.
- chr19:34,949,038–35,169,881, 18 genes, copy number 16: AC008555.6, ZNF792, GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN, HPN-AS1, AC020907.1, AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1, AC020907.2, FXYD7, FXYD5.
- chr19:38,199,836–38,852,347, 38 genes, copy number 17 (within-gene range 1–17): AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K, ACTN4, AC008649.2, CAPN12, AC022144.1, LGALS7, LGALS7B, RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2.

Autosomal genes at a single copy (total copy number 1): 11,246. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
